Somatic mutation profile of tumor specimen TCGA-P8-A5KC-01A (aliquot TCGA-P8-A5KC-01A-11D-A35D-08) from TCGA case TCGA-P8-A5KC, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 48.7 years (17,790 days).
Specimen TCGA-P8-A5KC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ee9e44f-87ff-491b-89ca-a625985ffece.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P8-A5KC-10A (Blood Derived Normal), aliquot TCGA-P8-A5KC-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75bba8e3-8440-4932-94e0-827f4ce24784

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS8 | c.1862A>G p.D621G | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs775696638; called by muse, mutect2, varscan2
- ARNT | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62230780; called by muse, mutect2
- EDAR | c.257T>C p.I86T | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.977); called by muse, mutect2
- HLX | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); called by muse, mutect2
- MYO5A | c.3536A>C p.K1179T | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- STAB2 | c.6202G>C p.E2068Q | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- STAT3 | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.153); called by muse, mutect2
- STK25 | c.350T>G p.I117S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FN1 | c.2340G>A p.L780= | Silent (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- INPP5D | c.2460T>C p.I820= (on ENST00000445964 / NM_001017915.3; = p.I819= on NM_005541.5) | Silent (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- ZDHHC8 | c.915G>A p.R305= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- MAGED1 | c.46-340C>T | Intron (SNP) | VAF 6/16 reads (38%) | catalogued as COSV58516587; called by muse, varscan2
- PDE4B | c.477-150G>A | Intron (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
